Surgical pathology report (de-identified scan), TCGA case TCGA-29-1761, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1761-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Surg Path [REDACTED]

TCGA-29-1761

CLINICAL HISTORY:

Pelvic organ prolapse, bilateral adnexal masses.

GROSS EXAMINATION:

A. "Omentum", received fresh. A 25 x 17 x 7 cm aggregate of firm, matted adipose and fibrous tissue with scabrous yellow tan cut surfaces. Representative sections are submitted as Blocks A1-A2.

B. "Right tube and ovary", received fresh. A 59.4 gram, 8.5 x 5.2 x 3.5 cm friable tan-pink mass with an identifiable 6.5 cm length of tube and focally adherent fat. One nodule is adjacent to the fimbriated end of the tube. Sectioning reveals predominantly compact yellow gray cut surfaces and peripheral cyst like formation lined by granular friable surfaces (B3). Representative sections to include fallopian tubes are submitted as Blocks B1-B3.

C. "Left tube and ovary and uterus", received fresh. A 62.2 gram portion of tissue composed of 5.4 x 4.5 x 3.5 cm uterine body with attached 6.5 cm length of fallopian tube and adjacent 3.5 x 2.5 x 1.0 cm ovary. No cervix is identified. The serosa is markedly nodule with a friable tan-gray mass extending onto the fallopian tube and ovarian serosa. The endometrium is granular tan-pink and less than 0.1 cm in thickness. The myometrium is 1.5 cm in thickness and contains a 1.9 cm circumscribed firm yellow intramural nodule and a focally calcified 1.5 cm diameter subserosal nodule. Sectioning the ovary reveals a compact whorled cut surface adjacent to the friable external nodules.

BLOCK SUMMARY:

- C1- posterior endomyometrium toward lower uterine segment.
- C2- anterior lower uterine segment.
- C3- anterior endomyometrium with intramural fibroids and serosal nodules.
- C4- left fallopian tube.
- C5- left ovary.

D. "Sigmoid colon", received fresh. An 8 cm segment of unoriented bowel with two stapled ends and multiple adherent friable red-tan nodules and matted adipose. The bowel segment is opened to reveal a tan velvety mucosa with no lesions identified. Sectioning reveals the friable external mass to encase the segment of bowel. Representative sections are submitted as Blocks D1-D2.

[REDACTED]

DIAGNOSIS:

A. "OMENTUM" (BIOPSY):

METASTATIC ADENOCARCINOMA INVOLVING OMENTAL TISSUE.

B. "RIGHT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

1. POORLY-DIFFERENTIATED SEROUS ADENOCARCINOMA OF OVARY.
- TUMOR SIZE 8.5 CM;
- TUMOR INVOLVES OVARIAN SURFACE.

TUMOR IMPLANTS EXTENSIVELY INVOLVE FALLOPIAN TUBE.

[REDACTED]

[page 2 of 2]
TCGA-29-1761

C. "LEFT TUBE AND OVARY AND UTERUS" (HYSTERECTOMY AND SALPINGO-OOPHORECTOMY):

1. POORLY-DIFFERENTIATED SEROUS ADENOCARCINOMA INVOLVING OVARIAN HILUM AND UTERINE SEROSA.
2. ENDOMETRIUM WITH CYSTIC ATROPHY.
3. MYOMETRIUM WITH LEIOMYOMA (1.3 CM).
4. NO CERVIX IDENTIFIED.
5. FALLOPIAN TUBE, NEGATIVE FOR CARCINOMA.

D. "SIGMOID COLON" (SEGMENTAL RESECTION):

SEGMENT OF COLON (8 CM), WITH SEROSAL IMPLANT OF METASTATIC ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4d139c04-a978-46f0-89a7-7cf4b4f10180 (TCGA-29-1761.63DEFA27-E729-4514-BDD2-D887C4100854.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).